Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5707, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5707-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

PRE-OP DIAGNOSIS: Right renal carcinoma.

POST-OP DIAGNOSIS: Not given.

PROCEDURE: Not given.

ADDENDA:**Addendum****SPECIAL PROCEDURE REPORT
MOLECULAR ANATOMIC PATHOLOGY FLUORESCENCE IN SITU HYBRIDIZATION ANALYSIS****Comment:**

Molecular fluorescence in situ hybridization (FISH) analysis demonstrates presence of trisomy of chromosomes 7 and 17 in both the papillary as well as the clear cell areas of this morphologically complex renal cell carcinoma. In addition, the papillary areas also show foci with tetrasomy of chromosome 17.

This molecular phenotype is most consistent with a papillary renal cell carcinoma.

Specimen type: Renal tumor.

Result:

	Centromere copy #	1	2	3	4+
Papillary Area	CEP1				
	CEP7		18(26.1%)	51(73.9%)	
	CEP17	8(12.7%)	11(17.5%)	33(52.4%)	11(17.4%)
Clear Cell Area	CEP1				
	CEP7		20(33.3%)	40(66.7%)	
	CEP17	6(8.5%)	16(22.5%)	49(69.0%)	

Interpretation guidelines:

Chromosomal losses are considered significant if present in greater than 30% of cells. The loss is indeterminate if present in 20-30% of cases. The loss is considered artifactual if seen in less than 20% of cases.

Chromosomal gains are considered significant if present in greater than 20% of cells. The gain is considered artifactual if seen in less than 20% of cases.

Probes used: CEP1 (1p11.1q11.1), CEP7 (7p11.1q11.1), CEP17 (17p11.1q11.1).

At least 25 cells are analyzed. The signal distribution for targeted foci of renal carcinoma is recorded. If the test results are not consistent with the clinical findings, and/or diagnostic, a consultation between pathologist and treating physician is warranted.

This test was developed and its performance characteristics determined by the University of Pittsburgh, Department of Pathology, as required by the regulations.

FINAL DIAGNOSIS:**RIGHT KIDNEY, NEPHRECTOMY –**

- A. RENAL CELL CARCINOMA (3.4 CM), FURHMAN NUCLEAR GRADE 3 / 4.
- B. THE TUMOR SHOWS BOTH PAPILLARY AND CLEAR CELL FEATURES (see comment).
- C. THE RENAL CELL CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE KIDNEY.
- D. THE MARGINS OF RESECTION ARE FREE OF TUMOR.
- E. THE URETERAL AND VASCULAR MARGINS OF RESECTION ARE UNREMARKABLE.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION SEEN.
- G. THE TUMOR SHOWS PROMINENT NECROSIS.
- H. THE SURROUNDING NON-NEOPLASTIC KIDNEY IS ESSENTIALLY UNREMARKABLE (see comment).
- I. TNM STAGE: T1a, Nx, Mx.

COMMENT:

The renal cell carcinoma shows prominent necrosis. In addition, the tumor has a mixed morphology with papillary and clear cell features. The exact characterization of this lesion will be performed after molecular testing has been accomplished. The results of the molecular tests, as well as their interpretation, will be reported in an addendum.

The non-neoplastic renal parenchyma distant from the tumor is unremarkable. However, the peritumoral renal parenchyma shows prominent glomerular sclerosis and focal areas of interstitial inflammation. Clinical and serologic correlation is suggested.

[page 2 of 2]
MICROSCOPIC:**SYNOPTIC - PRIMARY Kidney/Renal Pelvis/Ureter TUMORS**

A. Side: 1	1. Right	2. Left	
B. Location: 1			
1. Kidney (parenchyma - cortex/medulla)		3. Ureter	
2. Kidney (pelvis)		4. Kidney and ureter	
C. Procedure: 2			
1. Partial nephrectomy		4. Ureterectomy	
2. Simple nephrectomy		5. Other	
3. Radical nephrectomy			
D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass):		3.4 cm	
E. Type of malignant neoplasm: 1/2			
1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)		11. Urothelial carcinoma, small cell/neuroendocrine carcinoma	
2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)		12. Urothelial carcinoma, mixed	
3. Renal cell carcinoma, chromophobe cell type		13. Juxtaglomerular cell tumor	
4. Renal cell carcinoma, oncocytic		14. Wilms' tumor	
5. Renal cell carcinoma, sarcomatoid		15. Rhabdoid tumor	
6. Collecting duct carcinoma		16. Clear cell sarcoma	
7. Urothelial carcinoma, TCCa (non-invasive)		17. Congenital mesoblastic nephroma	
8. Urothelial carcinoma, TCCa (invasive ± in-situ)		18. Sarcoma (non-clear cell)	
9. Urothelial carcinoma, squamous carcinoma		19. Lymphoma/leukemia	
10. Urothelial carcinoma, adenocarcinoma		20. Other	
F. Histologic grade			
F1. Fuhrman grade (for RCC; grades 1-4): 3			
F2. Ash grade (grade 1-4): #			
F3. WHO grade (grade 1-3): # (for TCCa)			
F4. 1998 WHO/ISUP Classification: #			
1. LMP	2. LG	3. HG	
F5. Other malignant neoplasms (grades 1-3): #			
G. Non-neoplastic and other conditions: # / # / # / #			
1. Glomerulopathy			
2. Interstitial nephritis			
3. Pyelonephritis			
4. Nephrolithiasis			
5. Papillary necrosis			
6. Chronic parenchymal disease			
7. Other			
H. Margins of resection: 2		1. Positive	2. Negative
I. Mitotic activity: # per 10 high power fields			
J. Angiolymphatic invasion			
J1. Macroscopic (e.g., renal vein thrombus): 2		1. Positive	2. Negative
J2. Microscopic: 2		1. Positive	2. Negative
K. Number of positive lymph nodes: #			
L. Total number of lymph nodes examined: #			
M. Extracapsular spread of lymph node metastases: #			
1. Yes	2. No		
N. Adrenal gland:			
N1. Present 2	1. Yes	2. No	
N2. Involvement by renal neoplasm: 3	1. Yes	2. No	3. Not Applicable
N3. Other adrenal pathology: 3	1. Yes	2. No	3. Not applicable
O. TNM stage: T 1a N x M x			

Source: NCI Genomic Data Commons file b93ace5b-0bc9-4c26-86e9-b017df67f957 (TCGA-B0-5707.CF09BC1D-0255-4BCD-8553-0B64331748DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).